Somatic mutation profile of tumor specimen TARGET-20-PASULX-09A (aliquot TARGET-20-PASULX-09A-01D) from TARGET case TARGET-20-PASULX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,981 days).
Specimen TARGET-20-PASULX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8cbe6b-cb28-4b4a-9086-7f1f35e3a52f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASULX-14A (Bone Marrow Normal), aliquot TARGET-20-PASULX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323deefc-1432-4d95-9fad-8173ba18d4bb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 24/72 reads (33%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- GATA2 | c.949A>C p.N317H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62003319; called by muse, mutect2, varscan2
